Surgical pathology report (de-identified scan), TCGA case TCGA-XF-A9SM, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Southern California, specimen TCGA-XF-A9SM-01A (Primary Tumor).

[page 1 of 5]
Collected:

Ordered by:

Location:

FINAL DIAGNOSIS:

RIGHT DISTAL URETER (A):

FROZEN SECTION DIAGNOSIS:

- NO CARCINOMA IN SITU

FINAL DIAGNOSIS:

- BENIGN URETER

- NO CARCINOMA IN SITU OR MALIGNANCY IDENTIFIED

LEFT DISTAL URETER (B):

FROZEN SECTION DIAGNOSIS:

- NO CARCINOMA IN SITU

FINAL DIAGNOSIS:

- BENIGN URETER

- NO CARCINOMA IN SITU OR MALIGNANCY IDENTIFIED

URETHRAL MARGIN (C):

FROZEN SECTION DIAGNOSIS:

- NO CARCINOMA IN SITU

- CHRONIC INFLAMMATION WITH GRANULOMAS, CONSISTENT WITH BCG

FINAL DIAGNOSIS:

- NO CARCINOMA IN SITU

- CHRONIC INFLAMMATION WITH GRANULOMAS, CONSISTENT WITH BCG THERAPY

BLADDER (C):

- POORLY DIFFERENTIATED TRANSITIONAL CELL CARCINOMA WITH GLANDULAR DIFFERENTIATION, NUCLEAR GRADE 4 OUT OF 4, MEASURING 7 X 5 X 3 CM

- TUMOR INVADDES THROUGH FULL THICKNESS OF MUSCULARIS PROPRIA INTO SURROUNDING FIBROFATTY TISSUE

- ALL INKED MARGINS AND PERITONEAL SURFACE ARE FREE OF TUMOR

- NO LYMPHOVASCULAR SPACE INVASION IDENTIFIED

- CARCINOMA IN SITU (SLIDE C13)

- UNINVOLVED BLADDER SHOWS MARKED CHRONIC CYSTITIS AND CYSTITIS GLANDULARIS, AND GRANULOMATOUS REACTION

PROSTATE (C):

- BILATERAL PROSTATIC ADENOCARCINOMA, GLEASON' S SCORE 6 (3+3)

- TUMOR FOCALLY INVADDES INTO BUT NOT THROUGH CAPSULE

- INKED RADIAL MARGINS ARE FREE OF TUMOR

- NO LYMPHOVASCULAR SPACE INVASION IDENTIFIED

- BILATERAL SEMINAL VESICLES AND VASA DEFERENTIA, FREE OF TUMOR

- GRANULOMATOUS PROSTATITIS CONSISTENT WITH BACILLE CALMETTE-GUERIN (BCG) THERAPY

PARA-AORTIC LYMPH NODES (D):

- NO METASTATIC CARCINOMA IDENTIFIED IN 19 LYMPH NODES EXAMINED (0/19)

PARACAVAL LYMPH NODES (E):

- NO METASTATIC CARCINOMA IDENTIFIED IN EIGHT LYMPH NODES EXAMINED (0/8)

RIGHT COMMON ILIAC LYMPH NODES (F):

- NO METASTATIC CARCINOMA IDENTIFIED IN THREE LYMPH NODES EXAMINED (0/3)

LEFT COMMON ILIAC LYMPH NODES (G):

- NO METASTATIC CARCINOMA IDENTIFIED IN NINE LYMPH NODES EXAMINED (0/9)

RIGHT EXTERNAL ILIAC LYMPH NODES (H):

- NO METASTATIC CARCINOMA IDENTIFIED IN 13 LYMPH NODES EXAMINED (0/13)

RIGHT LYMPH NODE OF CLOQUET (I):

ONE

ICD-O-3

Carcinoma, urothelial NOS 8120/3

Path Carcinoma, transitional cell NOS 8120/3

Site Bladder NOS 067.9

403/26/14

0% glandular, per TSS.

10% squamous, per TSS.

[page 2 of 5]
Collected:

Ordered by:

Location:

- NO METASTATIC CARCINOMA IDENTIFIED IN TWO LYMPH NODES EXAMINED (0/2)

RIGHT HYPOGASTRIC/OBTURATOR LYMPH NODES (J):

- NO METASTATIC CARCINOMA IDENTIFIED IN 15 LYMPH NODES EXAMINED (0/15)

LEFT EXTERNAL ILIAC LYMPH NODES (K):

- NO METASTATIC CARCINOMA IDENTIFIED IN SEVEN LYMPH NODES EXAMINED (0/7)

LEFT LYMPH NODE OF CLOQUET (L):

- NO METASTATIC CARCINOMA IDENTIFIED IN ONE LYMPH NODE EXAMINED (0/1)

LEFT HYPOGASTRIC/OBTURATOR LYMPH NODES (M):

- NO METASTATIC CARCINOMA IDENTIFIED IN 13 LYMPH NODES EXAMINED (0/13)

LEFT PRESACRAL LYMPH NODES (N):

- NO METASTATIC CARCINOMA IDENTIFIED IN SEVEN LYMPH NODES EXAMINED (0/7)

RIGHT PRESACRAL LYMPH NODES (O):

- NO METASTATIC CARCINOMA IDENTIFIED IN THREE LYMPH NODES EXAMINED (0/3)

PRESACRAL LYMPH NODES (P):

- NO METASTATIC CARCINOMA IDENTIFIED IN FOUR LYMPH NODES EXAMINED (0/4)

LEFT PROXIMAL URETER (Q):

- BENIGN URETER
- NO CARCINOMA IN SITU OR MALIGNANCY IDENTIFIED

RIGHT PROXIMAL URETER (R):

- BENIGN URETER
- NO CARCINOMA IN SITU OR MALIGNANCY IDENTIFIED

PROSTATE: pT2cN0MX

BLADDER: pT3bN0MX

INTRAOPERATIVE DIAGNOSIS:

FROZEN SECTION DIAGNOSIS:

AFS: Right distal ureter:

- no carcinoma in situ

BFS: Left distal ureter:

- no carcinoma in situ

CFS: Urethral margin:

- no carcinoma in situ
- chronic inflammation with granulomas consistent with BCG

GROSS DESCRIPTION:

A: The specimen is received fresh from the O.R. and labeled "Right distal ureter."

It consists of a segment of ureter measuring 0.4 cm in length and 0.6 cm in circumference. The specimen is entirely submitted for frozen section in cassette AFS.

B: The specimen is received fresh from the O.R. and labeled "Left distal ureter."

It consists of a segment of ureter measuring 0.2 cm in length and 0.8 cm in circumference. The specimen is entirely submitted for frozen section in cassette BFS.

C: The specimen is received fresh from the O.R. and labeled "Bladder & prostate."

[page 3 of 5]
Collected

Ordered by

Location

It consists of bladder and prostate measuring 23 x 18 x 6 cm overall. The peritoneum measures 24 x 15 x 1 cm. The peritoneal surface is smooth with a focal area of adhesion measuring 2 x 2 cm. The bladder measures 9 x 6 x 5 cm. The right distal ureter measures 7 cm in length and 1 cm in circumference. The left distal ureter measures 6 cm in length and 0.4 cm in circumference. The ureteral mucosa is smooth with no gross lesion identified. There is a large, gray-white, firm lesion located in the anterior and the right side of bladder wall measuring 7 x 5 x 3 cm. The tumor grossly invades the full thickness of the bladder wall and into surrounding soft tissue. The soft tissue margin is negative of tumor grossly. The prostate measures 7 x 6 x 5 cm. The prostatic urethra measures 4.5 cm in length and 2 cm in circumference. The verumontanum measures 0.7 x 0.5 x 0.4 cm. There is no gross lesion identified in the prostatic urethra. The left prostate is inked blue, and the right prostate is inked black. The prostate is serially sectioned and reveals a focal yellow lesion located in the midprostate, measuring 0.3 cm in maximum dimension. Representative sections are submitted in 33 cassettes.

D: The specimen is received in formalin and labelled "Para aortic lymph nodes." It consists of multiple pieces of yellow fatty tissue measuring 6 x 5 x 2 cm in aggregate. There are multiple lymph nodes identified. Representative sections are submitted in four cassettes.

E: The specimen is received in formalin and labelled "Para caval lymph nodes." It consists of multiple pieces of yellow-tan fatty tissue measuring 5 x 3 x 1 cm in aggregate. There are multiple lymph nodes identified. Representative sections are submitted in two cassettes.

F: The specimen is received in formalin and labelled "Right common iliac lymph nodes." It consists of multiple pieces of yellow fatty tissue measuring 3 x 3 x 1 cm in aggregate. There are multiple lymph nodes identified. Representative sections are submitted in one cassette.

G: The specimen is received in formalin and labelled "Left common iliac lymph nodes." It consists of a piece of yellow fatty tissue measuring 2 x 2 x 1 cm. There are multiple lymph nodes identified. Representative sections are submitted in one cassette.

H: The specimen is received in formalin and labelled "Right external iliac lymph nodes." It consists of a piece of yellow fatty tissue measuring 6 x 3 x 1 cm. There are multiple lymph nodes identified. Representative sections are submitted in three cassettes.

I: The specimen is received in formalin and labelled "Right lymph node of cloquet." It consists of a piece of yellow fatty tissue measuring 2 x 1 x 0.6 cm. The specimen is bisected and entirely submitted in one cassette.

J: The specimen is received in formalin and labelled "Right hypogastric / obturator lymph nodes." It consists of multiple pieces of yellow fatty tissue measuring 6 x 5 x 2 cm in aggregate. There are multiple lymph nodes identified. The largest piece measures 2 cm in maximum dimension. Representative sections are submitted in one cassette.

K: The specimen is received in formalin and labelled "Left external iliac nodes." It consists of a piece of yellow fatty tissue measuring 5 x 3 x 2 cm. There are multiple lymph nodes. The largest one measures 3 cm. Representative sections are submitted in three cassettes.

L: The specimen is received in formalin and labelled "Left lymph node of cloquet." It consists of a piece of yellow fatty tissue measuring 1.5 x 1 x 0.6 cm. The specimen is bisected and entirely submitted in one cassette.

[page 4 of 5]
Collected

Ordered by

Location

M: The specimen is received in formalin and labelled "Left hypogastric / obturator lymph nodes." It consists of a piece of yellow fatty tissue measuring 5 x 4 x 3 cm. There are multiple lymph nodes identified. The largest piece measures 3 cm in maximum dimension. Representative sections are submitted in four cassettes.

N: The specimen is received in formalin and labelled "Left presciatic lymph nodes." It consists of multiple pieces of yellow fatty tissue measuring 3 x 2 x 1 cm in aggregate. The specimen is entirely submitted in one cassette.

O: The specimen is received in formalin and labelled "Right presciatic lymph nodes." It consists of multiple pieces of yellow fatty tissue measuring 3 x 2 x 1 cm in aggregate. The specimen is entirely submitted in one cassette.

P: The specimen is received in formalin and labelled "Presacral lymph nodes." It consists of multiple pieces of yellow fatty tissue measuring 4 x 2 x 1 cm in aggregate. There are multiple lymph nodes identified. The specimen is entirely submitted in three cassettes.

Q: The specimen is received in formalin and labelled "Left proximal ureter." It consists of a segment of ureter measuring 2 cm in length and 0.5 cm in diameter. Representative sections are submitted in one cassette.

R: The specimen is received in formalin and labelled "Right proximal ureter." It consists of a segment of ureter measuring 1.5 cm in length and 0.5 cm in diameter. Representative sections are submitted in one cassette.

SECTIONS:

AFS: frozen section, right distal ureter all embedded
BFS: frozen section, left distal ureter all embedded
CFS: frozen section, urethral margin
C1: right ureter
C2: left ureter
C3: right perivesical fat
C4: left perivesical fat
C5: peritoneal adhesion
C6: left bladder mucosa
C7,8: posterior bladder mucosa
C9: posterior bladder mucosa with diverticula
C10: trigone
C11-16: bladder tumor
C17: one lymph node
C18: right seminal vesicle and vas deferens
C19: left seminal vesicle and vas deferens
C20: right apex
C21: left apex of the prostate
C22: right midprostate
C23: left midprostate with yellow lesion
C24: right anterior midprostate
C25: right posterior midprostate
C26: left anterior midprostate
C27: left posterior midprostate
C28: right anterior proximal prostate
C29,30: right posterior proximal prostate
C31-33: left proximal prostate from anterior to posterior
D1-4: multiple para-aortic lymph nodes
E1,2: multiple paracaval lymph nodes
F: right common iliac lymph nodes
G: left common iliac lymph nodes
H1-3: right external iliac lymph nodes
I: right lymph node of Cloquet all embedded

[page 5 of 5]
REPORT

Collected:

Ordered by:

J1,2: multiple right hypogastric/obturator lymph nodes
J3: portion of largest lymph node
J4: one lymph node, bisected
K1: multiple left external iliac lymph nodes
K2: multiple lymph nodes
K3: portion of largest lymph node
L: left lymph node of Cloquet all embedded
M1-3: multiple left hypogastric/obturator lymph nodes
M4: portion of largest lymph node
N: left presciatic lymph nodes all embedded
O: right presciatic lymph nodes all embedded
P1-3: presacral lymph nodes all embedded
Q: left proximal ureter
R: right proximal ureter

MICROSCOPIC DESCRIPTION:

A-R: See final microscopic-diagnoses.

Signed by:

ELECTRONIC SIGNATURE

POST-OPERATIVE DIAGNOSIS:

Same as preop

PRE-OPERATIVE DIAGNOSIS:

Muscular invasion TCC bladder

ORDERING PHYSICIAN:

Ordering Physician:

Source: NCI Genomic Data Commons file 551f3383-dec5-41fa-9a25-19a19ba6be23 (TCGA-XF-A9SM.77D2B628-13A0-486E-866E-C10DDF141B2B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).